Somatic mutation profile of tumor specimen 0DTB8T from CCDI case PBCJGI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Tumor cells, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,039 days).
Specimen 0DTB8T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ca95963-000f-42d2-a75e-e9ee2cd3f218.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff5c7e12-d97e-4480-aa27-5a3b3a837bea

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 3, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.432); catalogued as rs1555774889; ClinVar: uncertain significance; called by muse, mutect2
- CD33 | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 105/480 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.313); catalogued as COSV99220100; called by muse, mutect2, varscan2
- DMXL1 | c.7934C>T p.A2645V | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60719530; called by muse, mutect2, varscan2
- HAPLN3 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs1287870721, COSV62086651; called by muse, mutect2, varscan2
- PGAP1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 13/371 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs964603373, COSV61323637, COSV61328508; called by muse, mutect2
- SRRM3 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs543352927; called by muse, mutect2, varscan2
- ASAP1 | c.560A>C p.H187P | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); called by muse, mutect2
- CD33 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 104/481 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DDC | c.227T>C p.F76S | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DST | c.15374C>T p.A5125V (on ENST00000361203 / NM_001374722.1; = p.A2713V on NM_015548.5) | Missense Mutation (SNP) | VAF 15/439 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); called by muse, mutect2
- GPR142 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2
- MYO15B | c.7406T>A p.L2469Q | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OTUD1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROKR1 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 36/387 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.16); called by muse, mutect2
- SRRM2 | c.4921T>C p.S1641P | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKAP9 | c.5766A>G p.T1922= (on ENST00000359028; = p.T1890= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/674 reads (6%) | catalogued as rs778672115; called by muse, mutect2
- ADPGK | c.840+91T>A | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- C19orf81 | c.*67C>G | 3'UTR (SNP) | VAF 10/113 reads (9%) | catalogued as rs1012574631; called by muse, mutect2
- DNM1L | c.251-86G>T | Intron (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- PIP5K1C | c.1920+1479C>T | Intron (SNP) | VAF 60/214 reads (28%) | catalogued as rs566966489; called by muse, mutect2, varscan2
